Gene-level copy-number profile of tumor specimen TARGET-40-PAUTYB-01A from TARGET case TARGET-40-PAUTYB, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.1 years (4,418 days).
Specimen TARGET-40-PAUTYB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.ef5ac7e5-ca44-592c-96ec-4640c6c916bc.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAUTYB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 359 have no estimate.
https://portal.gdc.cancer.gov/files/cf2944eb-74fc-4d97-a5b7-60bbbda05b70

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 521; copy number 1: 5; copy number 2: 20,087; copy number 3: 15,743; copy number 4: 21,405; copy number 5: 1,816; copy number 6: 222; copy number 7: 39; copy number 8: 19; copy number 9: 210; copy number 10: 27; copy number 11: 30; copy number 13: 2; copy number 15: 35; copy number 17: 12; copy number 18: 62; copy number 19: 2; copy number 21: 27.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:5,407,564–5,407,876, 1 gene: AL121757.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 407 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:99,873,200–114,791,929, 205 genes, copy number 9 (broad region; genes not listed).
- chr8:117,520,713–131,040,909, 200 genes, copy number 9–21 (within-gene range 2–21) (broad region; genes not listed).
- chr20:1,561,385–1,620,061, 2 genes, copy number 19 (within-gene range 2–19): SIRPB1, AL049634.3.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
